Surgical pathology report (de-identified scan), TCGA case TCGA-06-1087, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1087-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

06-1087

CLINICAL HISTORY

[REDACTED] with [REDACTED] had a temporal lesion biopsied that was consistent with a high grade neoplasm. On imaging there is a left temporal necrotic mass with a solid enhancing component.

OPERATIVE DIAGNOSES

Left temporal mass.

Operation/Specimen: A: Brain, left temporal tumor, biopsy

: Brain, left temporal tumor, biopsy

C: Brain, Left temporal tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, and C. Brain, left temporal, excisional biopsies and excision:

Glioblastoma with sarcomatous features.

See Microscopy Description and Comment.

COMMENT

In parts A and C there is a neoplastic proliferation of glial cells that has focal infiltrative areas with mitoses and microvascular cellular proliferation (part A). The bulk of the tumor is made of zones of very cellular groups of undifferentiated cells with brisk mitotic activity and high MIB1 proliferation index; these undifferentiated cells are contained within zones of a very vascular sarcomatous component. There are no neuronal elements.

In part A most of the tissue is necrotic, and only a couple of small fragments have the infiltrating glioblastoma.

In part B there is only a cluster of undifferentiated neoplasm surrounded by spindle cell tissue.

In part C there are extensive areas of necrosis and the sarcomatous component.

The findings are interpreted as a glioblastoma with sarcomatous features, i. e. a gliosarcoma.

[page 2 of 3]
=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, left temporal tumor, biopsy: Necrosis and occasional inflammatory cells, defer to permanents (consider abscess). Reported to physician of record, [REDACTED] [REDACTED]

B. Brain, left temporal tumor, biopsy: Necrosis and small foci of atypical cells, defer to permanents (consider neoplasm). Reported to physician of record, [REDACTED] [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A. Received are multiple fragments of soft tan tissue, approximately 1.0 x 0.8 x 0.4 cm. Samples are used for frozen sections and smears. The frozen residual is submitted in A1 and the unfrozen tissue is submitted in A2.

B. Received is a fragment of soft tan-reddish tissue, approximately 0.6 x 0.4 x 0.4 cm. Samples are used for frozen sections and smears. The frozen residual is submitted in B1 and the unfrozen tissue is submitted in B2.

[page 3 of 3]
C.

SPECIMEN: Left temporal tumor

FIXATIVE: Formalin

GENERAL: A 4.0 x 3.5 x 1.8 cm, 6.92 gm aggregate of multiple irregularly shaped fragments of gray tan brain tissue.

SECTIONS: C1-3 representative

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: In part A there is a moderate infiltrate of naked nuclei in cerebral tissue that is GFAP positive. Only a minority of neoplastic nuclei over express the p53 protein. The MIB-1 proliferation index in this area is at least 18%.

In parts C and D there is extensive necrosis. There are also small nests of very cellular undifferentiated cells that are negative with the glial (GFAP), neuronal markers (synaptophysin and NeuN), and epithelial markers (CK and CK7). There are also inter- anastomosing strands of very vascular tissue (positive structures with CD31 and CD34) that has sarcomatoid phenotype and is negative for smooth muscle actin (SMA). MelanA is negative in the undifferentiated cells, and weakly and diffusely reactive throughout the sarcomatous component (probably non-specific background). The MIB1 proliferation index in an undifferentiated area is about 25% (block B2).

SPECIAL STAIN: The Snook's stain demonstrates extensive reticulin deposition by the tumor cells in the sarcomatous areas.

TCID-9(s):

191.9 191.9

Histo Data

Part A: Brain, left temporal tumor, biopsy

Taken:	Received:
Stain/cnt	Block Ordered Comment
FS H/E x 1	1
H/E x 1	1
Retic x 1	1
TPS H/E x 1	1
mGFAP-DA x 1	2
H/E x 1	2
MGMT x 1	2
MIB1-DA x 1	2
P53DO7 x 1	2

Part B: Brain, left temporal tumor, biopsy

Taken:	Received:
Stain/cnt	Block Ordered Comment
FS H/E x 1	1
H/E x 1	1
TPS H/E x 1	1
mGFAP-DA x 1	2
E x 1	2
MIB1-DA x 1	2

Source: NCI Genomic Data Commons file 1ba26295-2972-4626-875e-7c1912e06dbc (TCGA-06-1087.36121B4D-6DDE-4223-9F7A-5CA50AD4F7B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).